Surgical pathology report (de-identified scan), TCGA case TCGA-86-8358, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Asterand, specimen TCGA-86-8358-01A (Primary Tumor).

[page 1 of 4]
[REDACTED]

[REDACTED]

	Case ID	Gross Description	Microscopic Description

[page 2 of 4]
Diagnosis Details	Comments	Formatted Path Report
		LUNG TISSUE CHECKLIST Specimen type: Lobectomy Tumor site: Lung Tumor size: 3.2 x 3.2 x 3.2 cm Histologic type: Adenocarcinoma Histologic grade: Poorly differentiated Tumor extent: Not specified Other tumor nodules: Not specified Lymph nodes: 0/6 positive for metastasis (Regional 0/6) Lymphatic invasion: Not specified Venous invasion: Not specified Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: Right- upper

[page 3 of 4]
	ID	Excision Date

[page 4 of 4]
Laterality

Right-upper

Source: NCI Genomic Data Commons file b773c378-a6dc-4a6b-8232-03e723bb224f (TCGA-86-8358.BDFC4CA3-CE4F-4206-B3FF-3733DF596E9D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).